Surgical pathology report (de-identified scan), TCGA case TCGA-RS-A6TO, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Memorial Sloan Kettering Cancer Center, specimen TCGA-RS-A6TO-01A (Primary Tumor).

[page 1 of 8]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED] Accession #: [REDACTED]
MRN: [REDACTED] Service: [REDACTED]
Account #: [REDACTED] Date of Procedure: [REDACTED]
DOB: [REDACTED] Date of Receipt: [REDACTED]
Physician: [REDACTED] Date of Report: [REDACTED]
CC: [REDACTED]
Patient Address: [REDACTED]

....

Clinical Diagnosis & History:
Malignant lesion. Right lower gingiva.

Specimens Submitted:

- 1: Anterior lip mucosa margin; excision (fs)
- 2: Right lateral margin buccal mucosa; excision (fs)
- 3: Left lateral margin buccal mucosa; excision (fs)
- 4: Posterior margin floor of mouth; excision (fs)
- 5: Right genial glossus margin; excision (fs)
- 6: Right neck, level 2B; excision
- 7: Right neck, level 1A; excision
- 8: Right neck, level 1B; excision
- 9: Right neck, level 2A; excision
- 10: Right neck, level 3; excision
- 11: Left lateral margin, buccal mucosa #2; excision
- 12: Left neck level 1B; excision
- 13: Right anterior mandible; composite resection

DIAGNOSIS:

1. Anterior lip mucosa margin; excision (fs):
- Benign squamous mucosa, with ulceration and reactive atypia
2. Right lateral margin buccal mucosa; excision (fs):
- Squamous mucosa with focal mild dysplasia
3. Left lateral margin buccal mucosa; excision (fs):
- Squamous cell carcinoma in situ present on frozen section slide only.
4. Posterior margin floor of mouth; excision (fs):
- Squamous mucosa with mild dysplasia
5. Right genial glossus margin; excision (fs):
- Benign skeletal muscle
6. Right neck, level 2B; excision:
Lymph Node Dissection:
Benign lymph nodes
Number of lymph nodes examined: 5

** Continued on next page **

ICD-0-3
Carcinoma, squamous
cell keratinizing NOS
Site Oral cavity C06.9
path
Lower gingiva C03.9
7/22/13

Date of
Procurement:

[page 2 of 8]
SURGICAL PATHOLOGY REPORT

Accession #:

----- Page 2 of 8

7. Right neck, level 1A; excision:

Lymph Node Dissection:

Metastatic squamous cell carcinoma
Number of lymph nodes examined: 7
Number of lymph nodes with metastatic disease: 2
Size of the largest lymph node involved by tumor: 0.5cm.
Size of the largest metastatic focus : 0.2 cm.
Extranodal extension is identified

8. Right neck, level 1B; excision:

Lymph Node Dissection:

Metastatic squamous cell carcinoma
Number of lymph nodes examined: 13
Number of lymph nodes with metastatic disease: 2
Size of the largest lymph node involved by tumor: 1.4cm.
Size of the largest metastatic focus : 1.4 cm.
Extranodal extension is not identified
Benign salivary gland with lymphocytic sialadenitis is also

present

9. Right neck, level 2A; excision:

Lymph Node Dissection:

Benign lymph nodes
Number of lymph nodes examined: 12

10. Right neck, level 3; excision:

Lymph Node Dissection:

Benign lymph nodes
Number of lymph nodes examined: 13

11. Left lateral margin, buccal mucosa #2; excision:

- Benign squamous mucosa

12. Left neck level 1B; excision:

Lymph Node Dissection:

Benign lymph nodes
Number of lymph nodes examined: 11
Benign salivary gland also present

13. Right anterior mandible; composite resection:

Tumor Type:

Invasive squamous cell carcinoma
Keratinizing

** Continued on next page **

[page 3 of 8]
----- Page 3 of 8

Histologic Grade:

Moderately differentiated

Tumor Size:

Greatest diameter is 3.0 cm

Maximal thickness 1.8cm

Tumor Location:

Lower gingiva

Tumor Invasion:

Tumor extends through bone

Tumor Necrosis:

Not identified

Vascular Invasion:

Not identified

Perineural Invasion:

Identified

Pattern of Invasion:

Invasive islands

Tumor Multicentricity:

Not identified

In situ carcinoma:

Not identified

Non-Neoplastic Mucosa:

Exhibits chronic inflammation

Surgical Margins:

Invasive carcinoma is present at the following margin(s): deep margin, lateral side

Bone Invasion:

Involves medullary space

Bone Margins:

Benign

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1. The specimen is received fresh for frozen section consultation labeled "Anterior lip mucosal margin" and consists of a tan mucosa tissue measuring 0.6 x 0.2 x 0.1 cm. The specimen is entirely submitted for frozen section.

Summary of sections:

** Continued on next page **

[page 4 of 8]
SURGICAL PATHOLOGY REPORT

----- Page 4 of 8
FSC - frozen section control

2. The specimen is received fresh for frozen section consultation labeled "Right lateral margin, buccal mucosa" and consists of a tan mucosa tissue measuring 1.0 x 0.2 x 0.2 cm. The specimen is entirely submitted for frozen section.

Summary of sections:
FSC - frozen section control

3. The specimen is received fresh for frozen section consultation labeled "Left lateral margin, buccal mucosa" and consists of a tan mucosa tissue measuring 0.8 x 0.2 x 0.2 cm. The specimen is entirely submitted for frozen section.

Summary of sections:
FSC - frozen section control

4. The specimen is received fresh for frozen section consultation labeled "Posterior margin, floor of mouth" and consists of a tan mucosa tissue measuring 0.3 x 0.2 x 0.2 cm. The specimen is entirely submitted for frozen section.

Summary of sections:
FSC - frozen section control

5. The specimen is received fresh for frozen section consultation labeled "Right genial glossus margin" and consists of a red soft tissue measuring 1.0 x 0.4 x 0.3 cm. The specimen is entirely submitted for frozen section.

Summary of sections:
FSC - frozen section control

6) The specimen is received fresh and is labeled "Right neck- level 2B". It consists of a 3.5 x 2.5 x 1.7 cm portion of adipose tissue, which upon sectioning displays 5 possible tan-red firm lymph nodes ranging from 0.3 x 0.3 x 0.3 cm to 0.7 x 0.6 x 0.3 cm. All identified lymph nodes are submitted.

Summary of sections:
LN- lymph nodes (5)

7) The specimen is received fresh and is labeled "Right neck- level 1A". It consists of a 3.0 x 1.8 x 1.3 cm portion of adipose tissue, which upon sectioning displays 10 possible tan-red firm lymph nodes ranging from 0.2 x

** Continued on next page **

[page 5 of 8]
SURGICAL PATHOLOGY REPORT

----- Page 5 of 8
0.1 x 0.1 cm to 1.0 x 0.5 x 0.3 cm. All identified lymph nodes are submitted.

Summary of sections:
LN- lymph nodes (10)

8) The specimen is received fresh and is labeled "Right neck- level 1B". It consists of a 5.8 x 4.5 x 3.6 cm portion of adipose tissue with attached 3.7 x 2.5 x 1.0 cm submandibular gland. The specimen is dissected to 19 possible tan-red lymph nodes and one grossly positive lymph node ranging from 0.2 x 0.2 x 0.1 cm to 1.6 x 1.4 x 0.8 cm. All identified lymph nodes and additional representative sections of the remaining specimen are submitted.

Summary of sections:
SMG -- submandibular gland
LN - lymph nodes
GPLN- grossly positive lymph node, representative

9) The specimen is received fresh and is labeled "Right neck- level 2A". It consists of a 4.1 x 3.4 x 2.0 cm portion of adipose tissue, which upon sectioning displays 11 possible tan-red firm lymph nodes ranging from 0.2 x 0.2 x 0.1 cm to 1.2 x 0.6 x 0.4 cm. All identified lymph nodes are submitted.

Summary of sections:
LN- lymph nodes (9)
BLN- bisected lymph nodes (2)

10) The specimen is received fresh and is labeled "Right neck- level 3". It consists of a 6.0 x 1.5 x 1.0 cm portion of adipose tissue, which upon sectioning displays 15 possible tan-red firm lymph nodes ranging from 0.2 x 0.1 x 0.1 cm to 0.7 x 0.3 x 0.3 cm. All identified lymph nodes are submitted.

Summary of sections:
LN- lymph nodes (15)

11) The specimen is received fresh, labeled "Left lateral margin-buccal mucosa # 2", and consists of a gray-tan irregular portion of mucosal lined soft tissue measuring 1.2 x 0.4 x 0.2 cm. The specimen is inked and entirely submitted.

Summary of sections:
U--undesignated

** Continued on next page **

[page 6 of 8]
SURGICAL PATHOLOGY REPORT

----- Page 6 of 8
12) The specimen is received fresh, labeled "Left neck level 1B" and consists of a 4.8 x 2.0 x 1.4 cm fragment of adipose tissue with attached 3.4 x 3.2 x 0.8 cm grossly unremarkable salivary gland. Sectioning the adipose tissue reveals a tan, soft, ovoid, tan-pink lymph nodes, ranging from 0.3 to 1.2 cm in greatest dimension. The largest lymph node is bisected and one half is submitted to the TPS and the remaining half is submitted for permanent. The remaining lymph nodes are entirely submitted and the remaining specimen is representatively submitted.

Summary of sections:

LN -- whole lymph nodes
BLN -- bisected lymph nodes
RHN -- remaining half of lymph node submitted to TPS
SG salivary gland

13) The specimen is received fresh labeled "right anterior composite resection of mandible, suture marks anterior" and consists of a resected portion of mandible with attached soft tissue and a mucosal surface measuring 7.2 x 3.5 x 3.2 cm in overall dimension. The mandible measures 7.2 x 2.2 x 1.9 cm. The soft tissue measures 6 x 3.5 3.1 cm with a mucosal surface measuring 5.2 cm (anterior to posterior) x 3.5 cm (lateral/buccal to medial/gingival). The mucosa is purple grey with a central ulcerated lesion measuring 3 x 1.8 cm, grossly located from the mucosal margins as follows: 0.9 cm-anterior, 0.6 cm-lateral/buccal, 1.5 cm- posterior and 0.6 cm-medial. The lesion is 1.1 cm from the anterior bone margin and 1.6 cm from the posterior bone margin. The specimen is inked anterior-purple, lateral/buccal-green, posterior-orange, medial-blue, deep-black. Upon sectioning the lesion has underlying invasive component, grossly extending to a depth of 1 cm, 0.2 cm from the nearest (lateral) margin. The lesion grossly extends into the underlying bone. A representative section of the lesion to the bone is submitted following decalcification. Perpendicular sections of the anterior and posterior margins are submitted; the remaining lesion is blocked out and submitted sequentially from anterior to posterior in its entirety. The bone margins are shaved. Gross photographs are taken. Tumor sampled for TPS. Representative sections are submitted.

Summary of sections:

ABM -- anterior bone margin, shaved
PBM -- posterior bone margin shaved
LB -- lesion to bone
AM -- anterior mucosal and soft tissue margin (perpendicular)
PM -- posterior mucosal and soft tissue margin (perpendicular)
L -- lesion (submitted sequentially from anterior to posterior)

Summary of Sections:

Part 1: Anterior lip mucosa margin; excision (fs)

Block	Sect.	Site	PCs
1	fs	1	

Part 2: Right lateral margin buccal mucosa; excision (fs)

Block	Sect.	Site	PCs
1	fs	1	

** Continued on next page **

[page 7 of 8]
SURGICAL PATHOLOGY REPORT

----- Page 7 of 8

Part 3: Left lateral margin buccal mucosa; excision

Block	Sect.	Site	PCs
1	fsc	1	

Part 4: Posterior margin floor of mouth; excision

Block	Sect.	Site	PCs
1	fsc	1	

Part 5: Right genial glossus margin; excision

Block	Sect.	Site	PCs
1	fsc	1	

Part 6: Right neck, level 2B; excision

Block	Sect.	Site	PCs
2	LN	5	

Part 7: Right neck, level 1A; excision

Block	Sect.	Site	PCs
2	LN	10	

Part 8: Right neck, level 1B; excision

Block	Sect.	Site	PCs
1	GPLN	1	
4	LN	19	
1	SMG	1	

Part 9: Right neck, level 2A; excision

Block	Sect.	Site	PCs
2	BLN	4	
2	LN	9	

Part 10: Right neck, level 3; excision

Block	Sect.	Site	PCs
3	LN	15	

Part 11: Left lateral margin, buccal mucosa #2; excision

Block	Sect.	Site	PCs
1	U	1	

Part 12: Left neck level 1B; excision

Block	Sect.	Site	PCs
1	BLN	2	
2	LN	12	
1	RHN	1	

** Continued on next page **

[page 8 of 8]
SURGICAL PATHOLOGY REPORT

----- Page 8 of 8

1 SG 1

Part 13: Right anterior mandible; composite resection

Block	Sect.	Site	PCs
1	ABM	1	
1	AM	1	
12	L	12	
1	PBM	1	
1	PM	1	

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. FROZEN SECTION DIAGNOSIS: Ulcerated squamous mucosa with atypia
PERMANENT DIAGNOSIS: Same.
2. FROZEN SECTION DIAGNOSIS: Squamous mucosa with moderate dysplasia
PERMANENT DIAGNOSIS: Same.
3. FROZEN SECTION DIAGNOSIS: In situ squamous cell carcinoma
PERMANENT DIAGNOSIS: Same.
4. FROZEN SECTION DIAGNOSIS: Squamous mucosa with mild dysplasia
PERMANENT DIAGNOSIS: Same.
5. FROZEN SECTION DIAGNOSIS: Benign skeletal muscle
PERMANENT DIAGNOSIS: Same.

** End of Report **

Source: NCI Genomic Data Commons file 6d2ed071-a50c-491f-a832-97cf55cc067c (TCGA-RS-A6TO.6F3960E4-4E90-4CFD-B318-61C96F3F5281.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).